Somatic mutation profile of tumor specimen 0DHY4V from CCDI case PBBUZI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.3 years (5,212 days).
Specimen 0DHY4V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 526d6468-c97b-4ced-a0fa-a75abca2afb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3b287ad-30c4-480d-a2d7-e85ba4b385c9

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNB3 | c.4091+1G>A p.X1364_splice | Splice Site (SNP) | VAF 200/482 reads (41%) | catalogued as COSV52069755; called by muse, varscan2
- KIF26B | c.3520G>T p.V1174L | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ZNF423 | c.1709T>A p.V570D (on ENST00000563137 / NM_001379286.1; = p.V562D on NM_015069.4) | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- ZKSCAN4 | c.603G>T p.G201= | Silent (SNP) | VAF 136/350 reads (39%) | called by muse, varscan2
- TINF2 | c.1129+34C>T | Intron (SNP) | VAF 46/306 reads (15%) | called by muse, varscan2
